FM case AD12264 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/f2658783-f5e5-42c0-9f3c-6f4f9881dbe9

Female, 19.6 years: Medullary carcinoma, NOS (ICD-O-3 8510/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
